Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3JE, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3JE-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to:

1CD-0-3

Melanoma, nos 8720/3

Site: Subcutaneous, back C 49.6

HISTOPATHOLOGY REPORT

lw 6/10/12

CLINICAL DETAILS

M77.

: History of a melanoma on back initially in (depth 3.7mm, level IV, mit 6/mm²). treated with WE + flap and (R) axillary SNB (->0.2mm dia deposit in one of the SNBs). MSLT2, but in : returned a positive FNA on the (R) axilla and had (R) axillary dissection on

Now has a nodule under the pedicle of the previous flap closure in (R) lower back. FNA () showed melanoma

Operation: Excision Stitch marks medial For Histopath, Tumour bank, and BRAF testing.

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking - half of tumour nodule.

MAGROSCOPIC DESCRIPTION

"RIGHT LOWER BACK MELANOMA - STITCH MARKS MEDIAL"

The specimen is received fresh for tissue banking. Specimen consists of an ellipse of skin, with a suture medial taken as 12 o'clock. It measures 80mm from 12 to 6 o'clock 40mm from 3 to 9 o'clock and 20mm in thickness.

On the surface of the skin there is a pigmented area, surrounded by a blue tattoo, measuring 25 x 20mm, the 3 o'clock margin is inked blue, the 6 o'clock margin is inked black.

On sectioning in the subcutis there is a nodule, measuring 15 x 12 x 10mm, half of the nodule is enucleated and given to tissue banking, measuring 12 x 12 x 7.5mm. The rest of the lesion is embedded in three blocks.

Case seen by

A-B. Tumour nodule.

C. Skin.

MICROSCOPIC REPORT

The (R) lower back excision shows a deposit of recurrent malignant melanoma.

The tumour forms a solitary rounded nodule in subcutis

Cytologically it has a pleomorphic epithelioid cytomorphology, with prominent nucleoli, mitoses 5/mm².

There is an active TILs response, with lymphocytes cuffing the tumour and producing tumour cell fallout (significant regression). Focally at the edge some small veins contain an inflammatory-cell rich plug (which could be regressed venous invasion). No perineural.

Surgical margins appear clear.

metastatic,
per TSS

SPECIAL INVESTIGATIONS

Block 1A is suitable for BRAF testing.

lw 6/10/12

[page 2 of 2]
Requested by:

Accession:

HISTOPATHOLOGY REPORT

SUMMARY

Skin (R) lower back / excision - Recurrent MALIGNANT MELANOMA.

REPORTED BY:

Source: NCI Genomic Data Commons file 51f0bae4-7e72-4bcf-bb5a-fd0597124b1b (TCGA-EE-A3JE.177DEE22-9A8E-48B2-AAD0-8E5E30865F1A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).